Surgical pathology report (de-identified scan), TCGA case TCGA-X2-A95T, project TCGA-SARC (Sarcoma), tissue source site University of Washington, specimen TCGA-X2-A95T-01A (Primary Tumor).

[page 1 of 4]
PATIENT ID:

COLLECTED:

RECEIVED:

CLINICAL DATA:

Endometrial carcinoma

ICD-O-3

Leiomyosarcoma NOS 8890/3
Site ^{chc} Uterus NOS C55.9
path Endometrium C54.1

QV3/12/14

GROSS DESCRIPTION:

A) Received in a container of formalin labeled "XXX, omentum" is a 425 g, 37 x 23 x 1.8 cm in greatest dimension yellow, lobulated portion of greater omentum. Serosa is tan, smooth, and glistening with a few attached fibrous adhesions. The omentum is sectioned and there are homogeneous, yellow, lobulated, fatty cut surfaces. No masses or lesions are identified. Representative sections are submitted in cassettes A1 through A5.

B) Received in a container of formalin labeled "XXX, right para-aortic lymph nodes" are multiple yellow, lobulated, nonoriented portions of fibrofatty tissue measuring 3 x 2.5 x 0.5 cm in aggregate dimension. There are fatty cut surfaces surrounding 2 lymph node candidates measuring 1.3 and 1.5 cm in greatest dimension. Lymph node candidates are entirely submitted in cassette B1.

C) Received in a container of formalin labeled "XXX, left para-aortic lymph nodes" are 3 yellow, lobulated, nonoriented portions of fibrofatty tissue measuring 2.5 x 1.5 x 0.6 cm in aggregate dimension. There are fatty cut surfaces admixed with 5 lymph node candidates ranging from 0.8 to 1.5 cm in greatest dimension. Representative sections are submitted labeled: C1 - 3 individual lymph node candidates; C2 - 2 individual lymph node candidates.

D) Received fresh designated "XXX, left tube and ovary" is a salpingo-oophorectomy specimen which includes a 3.2 x 1.5 x 1 cm ovary, a 5 cm long x 0.9 cm in diameter fallopian tube and moderate amount of mesosalpinx. The serosa of the ovary is tan cerebriform with no lesions identified. The specimen is bisected to reveal white-tan cut surfaces with a single corpus albicans. The serosa of the fallopian tube looks tan smooth and glistening with a 1.5 cm in diameter paratubal cyst. No papillary excrescences are identified. The fallopian tube is serially sectioned to reveal a dilated stellate lumen measuring up to 0.3 cm. No intraluminal masses are identified. Representative sections submitted in two cassettes. D1 - sections of ovary, normal fallopian tube and paratubal cyst; D2 - dilated fallopian tube.

E) Received fresh designated "XXX, right tube and ovary" is a salpingo-oophorectomy specimen which includes a 3 x 2 x 1 cm ovary and a 6 cm long x 0.7 cm in diameter fallopian tube and scant amount of mesosalpinx. The serosa of the ovary looks tan lobulated with no papillary excrescences identified. The ovary is bisected to reveal tan cut surfaces with multiple

[page 2 of 4]
PATIENT ID:

physiologic cysts. No masses are identified. The serosa of the fallopian tube looks pink smooth and glistening with no papillary excrescences identified and with a single 1 cm in diameter paratubal cyst. Fallopian tube is serially sectioned to reveal a patent stellate lumen with no intraluminal masses identified. The mesosalpinx is serially sectioned to reveal no masses. Representative sections submitted in two cassettes as follows: E1 - ovary and mesosalpinx; E2 - fallopian tube.

F) Received fresh designated "XXX, uterus" is a 365 gram, 13 x 8 x 6 cm uterus and cervix and vaginal cuff. The serosa appears tan smooth and glistening with no papillary excrescences or implants identified. The surgical margin is inked blue. The cervix has a barrel-shaped appearance. The ectocervix appears unremarkable with some erythema. The cervical os measures 1.5 cm in diameter. The specimen is bivalved to reveal a dilated cervical canal measuring up to 3.5 cm in diameter. The mucosa appears tan with few Nabothian cyst. The endometrial cavity is filled with a 7 x 4 x 3 cm hemorrhagic and pedunculated endometrial polyp arising from the posterior uterine wall. The uninvolved endometrium measures up to 0.1 cm and the myometrium measures 2.5 cm. The posterior lower uterine segment has some endometrial irregularities but no definite masses. The specimen is serially sectioned to reveal an endometrial polyp with variegated cut surfaces with areas of hemorrhage and areas of yellow discoloration. The lesion appears to invade at least the superficial aspect of the endometrium. The mass is also adjacent to an ill defined lobulated white firm mass. Representative sections submitted as follows: F1 and F2 - composite section anterior; F1 - cervix; F2 - lower uterine segment; F3 and F4 - composite section, anterior; F3 - endometrium and superficial myometrium; F4 - deep myometrium; F5 - superficial endomyometrium, anterior; F6 - left parametrium; F7, F8 - composite section; F7 - posterior cervix; F8 - posterior lower uterine segment; F9 - posterior lower uterine segment with endometrial thickening; F10 - F12 - composite section endometrial polyp and complete section of posterior myometrium; F13 and F14 - composite section of white firm mass and full section posterior myometrium; F15 - section of polyp with yellow discolored area; F16 - right parametrium.

G) Received in a container of formalin labeled "XXX left external iliac lymph nodes" are multiple yellow, lobulated, nonoriented portions of fibrofatty tissue measuring 4.5 x 4 x 1.5 cm in aggregate dimension. There are fatty cut surfaces admixed with numerous lymph node candidates ranging from 0.5 to 2.5 cm. Representative sections are submitted labeled: G1 - 1 bisected lymph node; G2 - 4 individual lymph node candidates; G3 through G5 - 1 trisected lymph node.

H) Received in a container of formalin labeled "XXX, left common iliac lymph node" are 3 yellow, lobulated, nonoriented portions of fibrofatty tissue measuring 2 x 1 x 0.8 cm in aggregate dimension. There are fatty cut surfaces surrounding a 2 cm in greatest dimension lymph node. The lymph node is bisected

[page 3 of 4]
PATIENT ID:

and has congested, otherwise unremarkable cut surfaces. Lymph node is entirely submitted in cassette H1.

I) Received in a container of formalin labeled "XXX, left obturator lymph node" is a 3.3 x 1.5 x 0.6 cm yellow, lobulated portion of fibrofatty tissue. There are fatty cut surfaces admixed with 2 lymph node candidates measuring 0.3 and 2.8 cm in greatest dimension. Largest candidate node is marked with blue ink and bisected. Two lymph node candidates are entirely submitted in cassette I1.

J) Received in a container of formalin labeled "XXX, right common iliac lymph node" are multiple yellow, lobulated, nonoriented portions of fibrofatty tissue measuring 2.5 x 1.5 x 0.5 cm in aggregate dimension. There are fatty cut surfaces admixed with 4 lymph node candidates averaging 0.4 cm in greatest dimension. Lymph node candidates are entirely submitted in cassette J1.

K) Received in a container of formalin labeled "XXX, right external iliac lymph node" are multiple yellow, lobulated, nonoriented portions of fibrofatty tissue measuring 4 x 3.5 x 1.5 cm in aggregate dimension. There are fatty cut surfaces admixed with a few lymph node candidates ranging from 0.5 to 2.5 cm. Representative sections are submitted labeled: K1 and K2 - 1 bisected lymph node; K3 - 3 individual lymph node candidates; K4 - 1 trisected lymph node.

L) Received in a container of formalin labeled "XXX, right obturator lymph nodes" are multiple yellow, lobulated, nonoriented portions of fibrofatty tissue measuring 3 x 2.5 x 0.5 cm in aggregate dimension. There are fatty cut surfaces surrounding 2 lymph node candidates measuring 1 and 2 cm in greatest dimension. Lymph node candidates are entirely submitted in cassette L1.

INTRAOPERATIVE CONSULTATION:

F) Gross examination: Fungating neoplastic mass involving greater than half of the myometrium

FINAL DIAGNOSIS:

F) Uterus, total hysterectomy (365 grams):

High grade leiomyosarcoma with the following features:

1. Sarcoma predominantly involves a 7cm pedunculated polyp in the endometrial cavity, and does not involve the lower uterine segment or cervix.
2. Sarcoma is invasive into the stalk of the polyp and the inner 1/2 of the myometrium (slide F13)

[page 4 of 4]
PATIENT ID: _____

3. Mitotic figures number >20 per 10 high power fields.
4. Necrosis is present, <50%.
5. Vascular invasion is present.
6. Sarcoma is composed of areas with identifiable smooth muscle histology and areas of high grade sarcoma without obvious histologic differentiation.
7. FNCLCC grade 3 of 3 (overall score 8 of 9): poor histologic differentiation (3 of 3), <50% necrosis (1 of 2) and high mitotic count (3 of 3).
8. Additional findings:
- a. Background inflamed endometrium with complex hyperplasia without atypia and polyps, no carcinoma identified.
- b. Cervix with inflamed microglandular hyperplasia and no neoplasm identified.
- c. Parametrium with no sarcoma identified.

A) Omentum, omentectomy: Fibroadipose tissue with no neoplasm identified.

B, C, G-L) Lymph nodes, as designated, excisions:

No carcinoma identified in 26 lymph nodes with reactive hyperplasia and focal microabscess formation (slide H1), including 2 right para-aortic, 5 left para-aortic, 6 left external iliac, 1 left common iliac, 1 left obturator, 4 right common iliac, 5 right external iliac and 2 right obturator.

D, E) Ovary and fallopian tube, left and right, bilateral salpingo-oophorectomy:

1. Bilateral fallopian tubes with acute salpingitis; no neoplasm identified.
2. Benign paratubal cysts.
3. Bilateral ovaries with no neoplasm identified.

COMMENT:

pTNM staging does not apply to leiomyosarcoma of uterus.

Procedures used to establish the diagnosis:

Routine

Resident

Pathologist

Electronically signed

In compliance with _____ regulations, the pathologist's signature on this report indicates that the case has been personally reviewed, and the diagnosis made or confirmed by, the Attending Pathologist. Microscopic examination was used to arrive at the diagnosis unless indicated otherwise.

Criteria	W 12/11/13	Yes	No

Source: NCI Genomic Data Commons file e09b16bb-3687-4bce-b869-dad8728b1874 (TCGA-X2-A95T.A913D73D-BAFB-4CC0-9B03-F5BB48AC1B62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).